MMRF case MMRF_2523 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d0bfbe4f-7930-4ea5-93f0-06b6457d8ea9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 666 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.0 years (20,458 days); ISS stage: III; Days to last known disease status: 666 days (1.8 years); Days to last follow up: 666 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 297 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 661 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 24 days; Days to treatment end: 641 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 666.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 155 mg/dL; Immunoglobulin A 18.3 g/L; Beta 2 Microglobulin 19.5 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 239 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.55 mmol/L; Albumin 33 g/L; Total Protein 9.6 g/dL; Glucose 6.38 mmol/L; C-Reactive Protein 0.25 mg/dL.
- Day 66 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.69 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 732 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 10.4 mmol/L.
- Day 150 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.77 mg/dL; Immunoglobulin G 8.58 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 1.07 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 11.1 ×10⁹/L; Platelets 358 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 6.27 mmol/L.
- Day 252 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.8 mg/dL; Hemoglobin 7.19 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.79 mmol/L.
- Day 297 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.5 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 5.24 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 5.77 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 437 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 92.3 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 12.7 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 7.63 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 5.23 mmol/L.
- Day 514 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.73 mg/dL; Immunoglobulin G 5.64 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.03 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 6.71 mmol/L.
- Day 584 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.8 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 6.77 mmol/L.

Other clinical attributes
- Day -23: Weight: 119 kg; Height: 149 cm.

Biospecimens (2 samples)
- Sample MMRF_2523_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_2523_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
